Somatic mutation profile of tumor specimen TARGET-10-PARGFL-09A (aliquot TARGET-10-PARGFL-09A-01D) from TARGET case TARGET-10-PARGFL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,499 days).
Specimen TARGET-10-PARGFL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd75f11d-bafe-428a-bdd1-eee1360bc45a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGFL-10A (Blood Derived Normal), aliquot TARGET-10-PARGFL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cd22e2f-1625-4158-b6cc-795fdbb20612

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, 3'UTR 2, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL2 | c.4046A>G p.D1349G (on ENST00000370717 / NM_001366005.1; = p.D1293G on NM_012302.4) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54697668; called by muse, mutect2, varscan2
- BCL11B | c.1294T>C p.C432R (on ENST00000357195 / NM_001282237.2; = p.C361R on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100595472, COSV61736189; called by muse, mutect2, varscan2
- EYA1 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.052); catalogued as rs199664417, COSV100380424, COSV58177967; called by mutect2, varscan2
- IMPG1 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs754453292, COSV64063586; called by muse, mutect2, varscan2
- LCAT | c.1022T>A p.V341E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV50452227; called by mutect2, varscan2
- MEGF10 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767856393, COSV57259309; called by muse, mutect2, varscan2
- NELL1 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54344006; called by muse, mutect2, varscan2
- OPN5 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs368242075; called by muse, mutect2, varscan2
- PYCR3 | c.439A>G p.S147G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55310048; called by mutect2, varscan2
- SLC43A2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as rs934353646, COSV56772541; called by muse, mutect2, varscan2
- STAG2 | c.3672+3A>T | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV54378072; called by mutect2, varscan2
- ZNF768 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs770452825, COSV63325348; called by muse, varscan2
- LCAT | c.1020_1021insCCGCGGCGGC p.V341Pfs*29 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- FAM71C | c.330G>A p.P110= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs765707994, COSV60943445; called by muse, mutect2, varscan2
- KANSL1 | c.2256C>T p.D752= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs760224197; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLC15A5 | c.1473C>T p.L491= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV61365188; called by muse, mutect2, varscan2
- CHST15 | c.*1305G>A | 3'UTR (SNP) | VAF 11/18 reads (61%) | catalogued as rs1036292426; called by muse, mutect2, varscan2
- EFTUD2 | c.619+30G>T | Intron (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- SPRYD4 | c.*6244G>A | 3'UTR (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
